Gene-level copy-number profile of specimen HCM-BROD-0644-C25-85M from HCMI case HCM-BROD-0644-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.7 years (25,096 days).
Specimen HCM-BROD-0644-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 62b77a7a-ff09-49bd-b8b1-e21003abdb27.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0644-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/96b9bff6-4207-4fb6-815a-971634c8bbda

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,676; copy number 2: 30,513; copy number 3: 19,751; copy number 4: 4,109; copy number 5: 1,104; copy number 6: 343; copy number 7: 89; copy number 8: 133; copy number 9: 11; copy number 10: 17; copy number 11: 1; copy number 12: 124; copy number 29: 12; copy number 47: 1; copy number 67: 5; copy number 90: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,842 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:27,217,714–27,496,994, 1 gene, copy number 5 (within-gene range 4–5): PURPL.
- chr5:28,213,359–29,396,095, 16 genes, copy number 5: AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, LINC02064.
- chr5:29,600,676–29,600,868, 1 gene, copy number 5: UBL5P1.
- chr5:31,053,565–32,651,976, 39 genes, copy number 5–6: RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061.
- chr5:33,987,174–34,124,528, 1 gene, copy number 5 (within-gene range 4–5): C1QTNF3-AMACR.
- chr5:34,017,858–34,124,385, 3 genes, copy number 5 (within-gene range 4–5): C1QTNF3, AC139792.2, AC139792.3.
- chr5:34,373,028–34,373,850, 1 gene, copy number 5: AC138853.1.
- chr5:36,192,589–36,302,114, 3 genes, copy number 5: NADK2, NADK2-AS1, RANBP3L.
- chr5:38,682,070–41,261,438, 32 genes, copy number 5–6: AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6.
- chr5:41,730,065–41,968,366, 9 genes, copy number 5: OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6.
- chr5:42,423,439–42,721,878, 1 gene, copy number 5 (within-gene range 4–5): GHR.
- chr5:42,729,138–42,924,535, 5 genes, copy number 5 (within-gene range 4–5): AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2.
- chr5:43,013,060–43,192,021, 8 genes, copy number 5 (within-gene range 4–5): AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3.
- chr5:43,287,470–44,658,569, 21 genes, copy number 5: HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224.
- chr5:45,254,948–45,696,498, 2 genes, copy number 5 (within-gene range 4–5): HCN1, AC117529.2.
- chr7:84,939,335–92,110,673, 74 genes, copy number 5 (broad region; genes not listed).
- chr7:97,851,677–99,325,826, 37 genes, copy number 5: ASNS, AC079781.5, AC005326.1, SNRPCP9, RPS3AP29, AC079781.1, AC079781.2, AC079781.3, OR7E7P, MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1, OCM2, RN7SL478P, LMTK2, BHLHA15, TECPR1, BRI3, BAIAP2L1, AC093799.1, RPS3AP26, PPIAP82, AC074121.1, NPTX2, RNU6-393P, TMEM130, TRRAP, MIR3609, AC004893.2, RNF14P3, SMURF1, AC004893.1, KPNA7, MYH16, AC004834.1.
- chr8:114,282,067–127,742,951, 177 genes, copy number 6–90 (broad region; genes not listed).
- chr12:43,633,093–43,633,281, 1 gene, copy number 5: AC090525.3.
- chr12:55,608,043–59,064,238, 175 genes, copy number 5–7 (broad region; genes not listed).
- chr12:61,600,067–61,600,843, 1 gene, copy number 5: DUX4L52.
- chr12:63,055,275–63,055,765, 1 gene, copy number 5: RSL24D1P5.
- chr12:64,759,484–66,257,434, 38 genes, copy number 5: TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1.
- chr12:74,537,835–74,664,141, 4 genes, copy number 5: ATXN7L3B, AC025257.1, AC123904.2, AC123904.1.
- chr14:18,333,726–51,730,727, 845 genes, copy number 5–12 (within-gene range 3–12) (broad region; genes not listed).
- chr15:87,859,751–101,979,093, 346 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,035. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
